Somatic mutation profile of tumor specimen C3N-01176-01 (aliquot CPT0078930009) from CPTAC case C3N-01176, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 71.0 years (25,950 days).
Specimen C3N-01176-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e5418d7-cde1-4a6b-bda8-e18224519e5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01176-31 (Blood Derived Normal), aliquot CPT0078970002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6cf1e4a7-ed9f-430c-8fd4-3f033f532178

The open-access MAF lists 96 somatic variants for this specimen: 68 protein-altering or splice-affecting, 18 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 18, Frame Shift Del 9, Intron 7, Splice Site 3, Nonsense Mutation 3, In Frame Del 2, Splice Region 2, Frame Shift Ins 1, 5'Flank 1, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.464-1G>A p.X155_splice | Splice Site (SNP) | VAF 107/300 reads (36%) | hotspot (GDC flag); catalogued as rs5030817, CS071276, CS941547, CS961706, COSV56542304, COSV56544494, COSV56544554, COSV56553901; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AL645922.1 | c.943A>T p.M315L | Missense Mutation (SNP) | VAF 97/439 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.028); catalogued as COSV100191489; called by muse, mutect2, varscan2
- CYP17A1 | c.521C>A p.A174E | Missense Mutation (SNP) | VAF 96/308 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM094743; called by muse, mutect2, varscan2
- EGLN2 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 75/260 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs140368149; called by muse, mutect2, varscan2
- HCAR2 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 81/603 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.835); catalogued as COSV61025040; called by muse, mutect2, varscan2
- ITGAE | c.1103A>C p.K368T | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV53989230; called by muse, mutect2, varscan2
- LAMC1 | c.2648C>G p.A883G | Missense Mutation (SNP) | VAF 59/251 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV51183234; called by muse, mutect2, varscan2
- MTOR | c.6688T>G p.L2230V | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63875963; called by muse, mutect2, varscan2
- MUC4 | c.11951C>G p.P3984R | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.811); catalogued as rs1345458249; called by muse, mutect2, varscan2
- NIPBL | c.5489C>T p.A1830V | Missense Mutation (SNP) | VAF 57/257 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM103803; called by muse, mutect2, varscan2
- OR2J2 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV65847939; called by muse, mutect2, varscan2
- RSC1A1 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV60779412; called by muse, mutect2, varscan2
- SLU7 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99775873; called by muse, mutect2, varscan2
- SMARCA4 | c.2731G>A p.G911S | Missense Mutation (SNP) | VAF 351/626 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100758185, COSV60798378; called by muse, mutect2, varscan2
- TEX13A | c.76del p.A26Pfs*25 | Frame Shift Del (DEL) | VAF 27/54 reads (50%) | catalogued as COSV100781881; called by mutect2, pindel, varscan2
- TIAL1 | c.109del p.S37Afs*4 | Frame Shift Del (DEL) | VAF 23/82 reads (28%) | catalogued as COSV64842938; called by mutect2, pindel, varscan2
- TTN | c.99515C>A p.T33172K (on ENST00000591111; = p.T25748K on NM_003319.4) | Missense Mutation (SNP) | VAF 44/222 reads (20%) | PolyPhen benign (0.006); catalogued as rs764562534; called by muse, mutect2, varscan2
- AL592490.1 | c.677C>T p.T226I | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- BAZ1A | c.546del p.D183Mfs*42 | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | called by mutect2, pindel, varscan2
- BSN | c.5015T>A p.V1672D | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CD28 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 63/273 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDKL5 | c.2046G>A p.E682= | Splice Region (SNP) | VAF 62/119 reads (52%) | called by muse, mutect2, varscan2
- CES3 | c.799C>T p.H267Y | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CTCF | c.1610T>A p.L537H | Missense Mutation (SNP) | VAF 64/236 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CUBN | c.509A>G p.D170G | Missense Mutation (SNP) | VAF 84/354 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUSP2 | c.668_674delinsT p.P223_E225delinsL | In Frame Del (DEL) | VAF 60/316 reads (19%) | called by pindel, varscan2*
- EHMT1 | c.436T>G p.S146A | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- ELOA | c.549del p.R183Sfs*83 | Frame Shift Del (DEL) | VAF 64/189 reads (34%) | called by mutect2, pindel, varscan2
- ENTPD7 | c.1421+2T>A p.X474_splice | Splice Site (SNP) | VAF 39/144 reads (27%) | called by muse, mutect2, varscan2
- EPHA4 | c.16T>A p.Y6N | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FFAR4 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 73/248 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- FNDC3A | c.1737_1738del p.H579Qfs*3 (on ENST00000492622 / NM_001079673.2; = p.H523Qfs*3 on NM_014923.5) | Frame Shift Del (DEL) | VAF 26/92 reads (28%) | called by pindel, varscan2
- GALC | c.1161G>T p.M387I | Missense Mutation (SNP) | VAF 75/275 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- GPAM | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 113/443 reads (26%) | called by muse, mutect2, varscan2
- GPR149 | c.332T>G p.M111R | Missense Mutation (SNP) | VAF 86/295 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- HCAR3 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.835); called by muse, varscan2
- HECW1 | c.1421A>T p.E474V | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- IFT88 | c.38del p.N13Mfs*39 (on ENST00000319980 / NM_001318493.2; = p.N4Mfs*39 on NM_006531.5 and 9 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 26/105 reads (25%) | called by mutect2, pindel, varscan2
- ITGA9 | c.1088A>G p.H363R | Missense Mutation (SNP) | VAF 142/362 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KCP | c.1988_1990del p.C663del (on ENST00000620378; = p.C723del on NM_001366122.1) | In Frame Del (DEL) | VAF 28/104 reads (27%) | called by mutect2, pindel
- KIAA1671 | c.407T>A p.F136Y | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MEIS2 | c.703C>T p.P235S (on ENST00000561208 / NM_170675.5; = p.P222S on NM_002399.3) | Missense Mutation (SNP) | VAF 59/226 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- MTMR12 | c.2201dup p.L734Ffs*7 | Frame Shift Ins (INS) | VAF 12/40 reads (30%) | called by mutect2, pindel, varscan2
- MYO1G | c.237T>A p.Y79* | Nonsense Mutation (SNP) | VAF 75/279 reads (27%) | called by muse, mutect2, varscan2
- MYRFL | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 66/290 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- NFRKB | c.3900A>G p.*1300Wext*2 (on ENST00000446488 / NM_001143835.2; = p.*1325Wext*2 on NM_006165.3) | Nonstop Mutation (SNP) | VAF 54/175 reads (31%) | called by muse, mutect2, varscan2
- NTN4 | c.541del p.C181Vfs*39 | Frame Shift Del (DEL) | VAF 55/191 reads (29%) | called by mutect2, pindel, varscan2
- NUMA1 | c.1179C>G p.H393Q | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUP205 | c.3913G>C p.E1305Q | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- PCLO | c.13528+1G>A p.X4510_splice | Splice Site (SNP) | VAF 16/76 reads (21%) | called by muse, mutect2, varscan2
- PCNX4 | c.3086C>G p.T1029S (on ENST00000406854 / NM_001330177.2; = p.T795S on NM_022495.5) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.074); called by muse, mutect2
- PNP | c.517_518del p.R173Gfs*13 | Frame Shift Del (DEL) | VAF 106/470 reads (23%) | called by pindel, varscan2
- PPP1R8 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PPWD1 | c.1706_1707del p.T569Ifs*4 | Frame Shift Del (DEL) | VAF 28/186 reads (15%) | called by mutect2, pindel, varscan2
- PSMA7 | c.530C>G p.T177S | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASAL1 | c.1375-3C>A | Splice Region (SNP) | VAF 46/242 reads (19%) | called by muse, mutect2, varscan2
- RGL2 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- RNF144B | c.322T>A p.F108I | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- SALL4 | c.787C>A p.H263N | Missense Mutation (SNP) | VAF 71/237 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- SAMD7 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 63/207 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SCYL2 | c.1177G>T p.V393F | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SEC23A | c.1481T>C p.I494T | Missense Mutation (SNP) | VAF 84/356 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- SMPD3 | c.254G>A p.W85* | Nonsense Mutation (SNP) | VAF 113/370 reads (31%) | called by muse, mutect2, varscan2
- SOCS5 | c.241A>T p.N81Y | Missense Mutation (SNP) | VAF 61/227 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TCF20 | c.5156_5158dup p.D1719_L1720insH | In Frame Ins (INS) | VAF 71/309 reads (23%) | called by pindel, varscan2
- TTN | c.28033T>C p.C9345R (on ENST00000591111; = p.C8418R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/162 reads (33%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WNT8B | c.934A>C p.K312Q | Missense Mutation (SNP) | VAF 70/251 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF568 | c.1595G>C p.C532S | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CBX2 | c.336C>A p.S112= | Silent (SNP) | VAF 88/355 reads (25%) | catalogued as COSV53970111; called by muse, mutect2, varscan2
- CEBPZ | c.966C>T p.N322= | Silent (SNP) | VAF 45/181 reads (25%) | called by muse, mutect2, varscan2
- CHD2 | c.4650G>A p.K1550= | Silent (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- CSNK1E | c.897G>T p.R299= | Silent (SNP) | VAF 44/166 reads (27%) | called by muse, mutect2, varscan2
- EPB42 | c.1278C>T p.D426= (on ENST00000441366 / NM_001114134.2; = p.D456= on NM_000119.3) | Silent (SNP) | VAF 115/392 reads (29%) | called by muse, mutect2, varscan2
- GABBR2 | c.1689C>T p.G563= | Silent (SNP) | VAF 54/214 reads (25%) | called by muse, mutect2, varscan2
- IGDCC3 | c.2292G>T p.T764= | Silent (SNP) | VAF 39/139 reads (28%) | called by muse, mutect2, varscan2
- LGALS9 | c.1062G>A p.Q354= (on ENST00000395473 / NM_009587.3; = p.Q322= on NM_002308.4) | Silent (SNP) | VAF 77/263 reads (29%) | catalogued as rs867765746; called by muse, mutect2, varscan2
- OPRM1 | c.126C>T p.S42= | Silent (SNP) | VAF 39/127 reads (31%) | called by muse, mutect2, varscan2
- OXER1 | c.975C>T p.S325= | Silent (SNP) | VAF 102/365 reads (28%) | catalogued as rs769126172, COSV54311865; called by muse, mutect2, varscan2
- PKHD1 | c.627T>C p.G209= | Silent (SNP) | VAF 14/374 reads (4%) | called by muse, mutect2
- PTPRT | c.3261G>T p.G1087= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as rs1322942438; called by muse, mutect2, varscan2
- SOX11 | c.510C>G p.L170= | Silent (SNP) | VAF 18/48 reads (38%) | called by muse, varscan2
- SRRM3 | c.1326G>C p.G442= | Silent (SNP) | VAF 25/93 reads (27%) | called by muse, mutect2, varscan2
- SUCLG2 | c.213T>A p.A71= | Silent (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- UST | c.582G>C p.R194= | Silent (SNP) | VAF 41/169 reads (24%) | called by muse, varscan2
- WNK3 | c.3492T>C p.S1164= | Silent (SNP) | VAF 46/80 reads (58%) | called by muse, mutect2, varscan2
- ZNF831 | c.3492C>A p.T1164= | Silent (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505934 del CTG | 5'Flank (DEL) | VAF 12/22 reads (55%) | called by mutect2, pindel, varscan2
- CRISP2 | c.515+163G>A | Intron (SNP) | VAF 19/73 reads (26%) | called by muse, mutect2, varscan2
- FSD2 | c.*3307del | 3'UTR (DEL) | VAF 15/62 reads (24%) | called by mutect2, pindel, varscan2
- GABRG3 | c.271-55249A>G | Intron (SNP) | VAF 26/147 reads (18%) | called by muse, mutect2, varscan2
- HBE1 | c.-267+102513C>A | Intron (SNP) | VAF 67/284 reads (24%) | called by muse, mutect2, varscan2
- IL10RA | c.67+182A>G | Intron (SNP) | VAF 50/627 reads (8%) | called by muse, mutect2
- LINC02873 | n.174A>T | RNA (SNP) | VAF 78/281 reads (28%) | called by muse, mutect2, varscan2
- MEIS1 | c.631-2257dup | Intron (INS) | VAF 36/98 reads (37%) | called by mutect2, pindel, varscan2
- RASGRP2 | c.-71-593A>G | Intron (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- ZNF789 | c.152-1843T>C | Intron (SNP) | VAF 64/326 reads (20%) | catalogued as COSV100507890; called by muse, mutect2, varscan2
